Somatic mutation profile of tumor specimen TCGA-E7-A97Q-01A (aliquot TCGA-E7-A97Q-01A-11D-A38G-08) from TCGA case TCGA-E7-A97Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,249 days).
Specimen TCGA-E7-A97Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fe9679d-ccca-45a4-8623-a1285b704532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A97Q-10A (Blood Derived Normal), aliquot TCGA-E7-A97Q-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47c163a1-4f28-423a-aecc-8555a66bf39e

The open-access MAF lists 68 somatic variants for this specimen: 57 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACSS1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60219695; called by muse, mutect2, varscan2
- AMPD1 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs753932146, COSV62415844; called by muse, mutect2, varscan2
- ARHGEF15 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV62725020, COSV62725217; called by muse, varscan2
- BDKRB1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs762755879, COSV53705998; called by muse, mutect2, varscan2
- CACNA1F | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1437727918, COSV59904154; called by muse, mutect2, varscan2
- CELA1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53329754; called by muse, mutect2, varscan2
- CUBN | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64714360; called by muse, mutect2, varscan2
- ELF3 | c.1007A>T p.Y336F | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62838087; called by muse, mutect2, varscan2
- EPS8L2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs369412251; called by muse, mutect2
- F8 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as CM0911157, COSV64272628; called by muse, mutect2, varscan2
- FBXL7 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61645082; called by muse, mutect2, varscan2
- FEM1C | c.1174T>A p.F392I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV57231423; called by muse, mutect2, varscan2
- FOXQ1 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV57258790; called by muse, mutect2, varscan2
- GDNF | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1478023030, COSV58479222; called by muse, mutect2, varscan2
- GHSR | c.681T>A p.C227* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99576970; called by muse, mutect2, varscan2
- GLOD5 | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV57489080; called by muse, mutect2, varscan2
- GPR50 | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54438699; called by muse, mutect2, varscan2
- GPRIN1 | c.1387A>T p.R463W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV56137938; called by muse, mutect2, varscan2
- GRID2 | c.2839A>G p.K947E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.899); catalogued as COSV56198470; called by muse, mutect2, varscan2
- HECTD2 | c.1329G>C p.K443N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53220550; called by muse, mutect2, varscan2
- IGF2BP3 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV51683548; called by muse, mutect2, varscan2
- KDM6A | c.233del p.R78Pfs*6 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV65036859, COSV65039510; called by mutect2, pindel, varscan2
- KIAA1755 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV54075943; called by muse, mutect2, varscan2
- LMTK3 | c.553T>G p.Y185D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54311674; called by muse, mutect2
- MAGEC3 | c.677T>C p.F226S | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53579344; called by muse, mutect2, varscan2
- MAP3K8 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99552147; called by muse, mutect2, varscan2
- MBTPS1 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV58570409; called by muse, mutect2, varscan2
- MSL3 | c.1244C>T p.A415V (on ENST00000312196 / NM_078629.4; = p.A249V on NM_006800.4) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV56492742; called by muse, mutect2, varscan2
- MYF5 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV57354974; called by muse, mutect2, varscan2
- NEB | c.3358A>T p.I1120L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV51157833; called by muse, mutect2, varscan2
- OAS2 | c.474_478del p.W158* | Nonsense Mutation (DEL) | VAF 18/95 reads (19%) | catalogued as COSV60802316; called by mutect2, pindel, varscan2
- ODC1 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99301299; called by muse, mutect2, varscan2
- P3H1 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 73/154 reads (47%) | catalogued as COSV99355254; called by muse, mutect2, varscan2
- PDGFD | c.886T>C p.C296R | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56376187; called by muse, mutect2, varscan2
- PHF20 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59185785; called by muse, mutect2, varscan2
- PPM1J | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517350; called by muse, mutect2, varscan2
- PRICKLE1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs369077719; called by muse, mutect2, varscan2
- PTPN20 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 88/745 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV55889246, COSV99886345; called by muse, mutect2, varscan2
- PYCARD | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56008215; called by muse, mutect2, varscan2
- RHOB | c.137T>G p.I46S | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55356028; called by muse, mutect2, varscan2
- RICTOR | c.2348A>G p.N783S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as rs769940015, COSV57121065; called by muse, mutect2, varscan2
- RPL6 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV99176140; called by muse, mutect2, varscan2
- RSPRY1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV68027598; called by muse, mutect2, varscan2
- RYR2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as CM1212784, COSV100770552; called by muse, mutect2
- SAFB | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV52650979; called by muse, mutect2, varscan2
- SPIN3 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as COSV66529146; called by muse, mutect2, varscan2
- TET1 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV65384282; called by muse, mutect2, varscan2
- TRIM71 | c.2246C>A p.S749Y | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV67470761, COSV67472322; called by muse, mutect2, varscan2
- TRMT10C | c.97_101del p.L33Nfs*17 | Frame Shift Del (DEL) | VAF 55/170 reads (32%) | catalogued as rs766131583; called by mutect2, pindel, varscan2
- ZFHX4 | c.7084A>C p.K2362Q | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.785); catalogued as rs754819020, COSV50717790; called by muse, mutect2, varscan2
- ZNF224 | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV61242203; called by muse, varscan2
- ZRANB3 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99923768; called by muse, mutect2, varscan2
- BHLHE41 | c.313dup p.Q105Pfs*46 | Frame Shift Ins (INS) | VAF 44/88 reads (50%) | called by mutect2, pindel, varscan2
- ELF3 | c.796dup p.S266Kfs*35 | Frame Shift Ins (INS) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- EP300 | c.3649del p.D1217Mfs*10 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- KDM6A | c.1157del p.N386Ifs*53 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- CRB1 | c.657A>G p.V219= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as COSV66339843; called by muse, mutect2, varscan2
- DMXL2 | c.4977G>A p.R1659= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1244294875, COSV51845103; called by muse, mutect2, varscan2
- DONSON | c.1224C>T p.T408= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51656076; called by muse, mutect2, varscan2
- DPP10 | c.1206T>C p.A402= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1249190294, COSV59682467; called by muse, mutect2, varscan2
- KCNE4 | c.621C>T p.N207= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1360435701, COSV56054448; called by muse, mutect2, varscan2
- KRTAP26-1 | c.505T>C p.L169= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV62128721; called by muse, mutect2, varscan2
- MFSD9 | c.54G>A p.E18= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV51493314; called by muse, mutect2, varscan2
- OR4A15 | c.372C>T p.I124= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as COSV59034953; called by muse, mutect2, varscan2
- RNF121 | c.426C>T p.I142= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV62316585; called by muse, mutect2, varscan2
- RPS6KA5 | c.36G>A p.A12= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1275845362, COSV100002646; called by muse, mutect2, varscan2
- ZNF460 | c.1671A>G p.E557= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs201265623, COSV64415597; called by muse, mutect2, varscan2
